Somatic mutation profile of tumor specimen TCGA-HT-7873-01B (aliquot TCGA-HT-7873-01B-11D-2395-08) from TCGA case TCGA-HT-7873, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.6 years (10,805 days).
Specimen TCGA-HT-7873-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8074ce2-27d5-42e5-84eb-55c4907ffa4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7873-10A (Blood Derived Normal), aliquot TCGA-HT-7873-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35e250a9-886a-4a4b-98bc-4325fd4f3deb

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Ins 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/82 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.8984A>C p.N2995T | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV71295871; called by muse, mutect2, varscan2
- ADCY4 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370445373, COSV60258220; called by muse, mutect2, varscan2
- ADGRL2 | c.2605T>C p.F869L (on ENST00000370717 / NM_001366005.1; = p.F856L on NM_012302.4) | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.649); catalogued as COSV54693018; called by muse, mutect2, varscan2
- ALDH7A1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs752523070, COSV63161130; called by muse, mutect2, varscan2
- ETV3 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58748694; called by muse, mutect2, varscan2
- FEV | c.136C>G p.Q46E | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55387543; called by muse, mutect2, varscan2
- LPO | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV51861803, COSV51863282; called by muse, mutect2, varscan2
- MAB21L1 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as COSV100077526, COSV59829312; called by muse, mutect2, varscan2
- NFAT5 | c.2431G>A p.V811I | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV63033637; called by muse, mutect2, varscan2
- PCSK4 | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs145279692; called by muse, mutect2, varscan2
- SIPA1L2 | c.4997G>A p.R1666Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as rs368811235; called by muse, mutect2, varscan2
- SP140 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.081); catalogued as COSV59447220; called by muse, mutect2, varscan2
- SPANXD | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs782493325, COSV65153383; called by muse, mutect2
- SSTR4 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781312298, COSV54797366; called by muse, mutect2, varscan2
- TANC1 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1179426836, COSV55098277; called by muse, mutect2, varscan2
- TRPA1 | c.2616G>T p.R872S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.58); catalogued as rs1034655616, COSV51576101; called by muse, mutect2, varscan2
- A1CF | c.436dup p.T146Nfs*16 | Frame Shift Ins (INS) | VAF 35/143 reads (24%) | called by mutect2, pindel, varscan2
- ALKBH1 | c.434_455+11del p.X145_splice | Splice Site (DEL) | VAF 19/202 reads (9%) | called by mutect2, pindel
- TP53 | c.1024_1031del p.R342Efs*2 | Frame Shift Del (DEL) | VAF 20/31 reads (65%) | called by mutect2, pindel, varscan2
- ALDH1A3 | c.123C>T p.H41= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs2229182, COSV60903294; called by muse, mutect2, varscan2
- KLHDC7A | c.1698G>A p.T566= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs761390895, COSV68771258; called by muse, mutect2, varscan2
- MRAP2 | c.489G>A p.K163= | Silent (SNP) | VAF 45/106 reads (42%) | catalogued as rs375536731; called by muse, mutect2, varscan2
- MYO9A | c.5526C>T p.N1842= | Silent (SNP) | VAF 47/153 reads (31%) | catalogued as rs751400479, COSV61859521; called by muse, mutect2, varscan2
- PPP1R26 | c.2826C>T p.T942= | Silent (SNP) | VAF 65/118 reads (55%) | catalogued as COSV63357607; called by muse, mutect2, varscan2
- SLC9A1 | c.450C>T p.G150= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs1467569903, COSV56054172; called by muse, mutect2, varscan2
- WWP1 | c.1443A>C p.T481= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV55365081; called by muse, mutect2, varscan2
- ZNF256 | c.366A>G p.A122= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as rs896730871, COSV56600145; called by muse, mutect2, varscan2
